Somatic mutation profile of tumor specimen TCGA-KC-A7F3-01A (aliquot TCGA-KC-A7F3-01A-21D-A33T-08) from TCGA case TCGA-KC-A7F3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.6 years (24,676 days).
Specimen TCGA-KC-A7F3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7edc77fa-5617-490e-ba28-ca1845509b97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A7F3-10A (Blood Derived Normal), aliquot TCGA-KC-A7F3-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d51d33a5-c265-437a-ac47-912fe07d7c45

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.4450C>T p.Q1484* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as COSV60060344; called by muse, mutect2, varscan2
- BRPF1 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100121121; called by muse, mutect2, varscan2
- C17orf80 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs1285978704, COSV99277870; called by muse, mutect2, varscan2
- CEP44 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV99639224; called by muse, mutect2, varscan2
- DLEC1 | c.4990G>A p.G1664R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as rs752168761, COSV57181296; called by muse, mutect2, varscan2
- FAM107B | c.209_210insC p.E70Dfs*10 (on ENST00000378458 / NM_001320737.1; = p.E245Dfs*10 on NM_031453.3) | Frame Shift Ins (INS) | VAF 22/96 reads (23%) | catalogued as COSV99473561; called by mutect2, pindel, varscan2
- GPR83 | c.679G>T p.D227Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV99703576; called by muse, mutect2, varscan2
- HECA | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as COSV100866159; called by muse, mutect2, varscan2
- LONP1 | c.809T>G p.V270G | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100638533; called by muse, mutect2
- LRBA | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs886227063, COSV63956715; called by muse, mutect2
- MINDY4 | c.130A>G p.R44G | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99518252; called by muse, mutect2, varscan2
- NLRP14 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as COSV100204633; called by muse, mutect2
- NRDE2 | c.612A>G p.I204M | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1444250256, COSV100583305; called by muse, mutect2, varscan2
- OR7D4 | c.488T>G p.M163R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100432612; called by muse, mutect2, varscan2
- PAX4 | c.668C>G p.A223G | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs372751660, COSV100489979; called by muse, mutect2, varscan2
- PPP2R3C | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808595; called by muse, mutect2, varscan2
- PSG3 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100548710; called by muse, mutect2, varscan2
- SPATA31D1 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 89/275 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1407418497, COSV100782529, COSV61196289; called by muse, mutect2, varscan2
- TAAR6 | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV99256495; called by muse, mutect2, varscan2
- TTLL5 | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100089259; called by muse, mutect2, varscan2
- ABCA10 | c.892_897del p.I298_F299del | In Frame Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- C17orf80 | c.669G>T p.V223= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99277865; called by muse, mutect2, varscan2
- FIGN | c.1773C>G p.L591= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV60763391; called by muse, mutect2, varscan2
- HNRNPR | c.1488C>G p.G496= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100164342; called by muse, mutect2, varscan2
- NCKAP1 | c.1164T>C p.H388= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100720019; called by muse, mutect2, varscan2
- NLRP5 | c.192G>C p.G64= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs1568480828, COSV101173411; called by muse, mutect2, varscan2
- RPL15 | c.414C>T p.F138= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100323185; called by muse, mutect2, varscan2
- WIPI1 | c.423C>T p.N141= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1298255095, COSV100048258, COSV50931692; called by muse, mutect2, varscan2
